Somatic mutation profile of tumor specimen C3L-02353-01 (aliquot CPT0112780009) from CPTAC case C3L-02353, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 80.1 years (29,240 days).
Specimen C3L-02353-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7bc278e-07e8-4ad2-bc33-4c3a111420b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02353-31 (Blood Derived Normal), aliquot CPT0115200002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/943164fa-27f0-4902-be9f-2f634e3d331a

The open-access MAF lists 351 somatic variants for this specimen: 213 protein-altering or splice-affecting, 88 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 88, Frame Shift Del 44, Intron 21, Frame Shift Ins 9, 5'UTR 9, Splice Region 9, RNA 8, 3'UTR 6, Nonsense Mutation 5, 5'Flank 5, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESR1 | c.1610A>C p.Y537S | Missense Mutation (SNP) | VAF 93/486 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52782924, COSV52783938; called by muse, mutect2, varscan2
- FBXL4 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 26/150 reads (17%) | catalogued as rs758395213, COSV57748207; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 104/225 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782603, CM109590, CM110122, CM132268, COSV100910106, COSV64289126, COSV64290825; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.3530C>T p.T1177M | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757572924, COSV62323604; called by muse, mutect2
- ABCC8 | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 70/339 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs201815564, COSV56853417; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2483del p.P828Rfs*120 | Frame Shift Del (DEL) | VAF 53/423 reads (13%) | catalogued as rs771762024; called by mutect2, pindel, varscan2
- ADGB | c.2856G>A p.M952I | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs375907760; called by muse, mutect2, varscan2
- AGRN | c.4472C>T p.T1491I | Missense Mutation (SNP) | VAF 79/488 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV65070987; called by muse, mutect2, varscan2
- AIPL1 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 51/282 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773203055; called by muse, mutect2, varscan2
- ALS2 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as rs1260922548; called by muse, mutect2, varscan2
- ANKRD31 | c.1407del p.E470Kfs*3 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | catalogued as rs1171871289; called by mutect2, varscan2
- ATN1 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); catalogued as rs782443835, COSV63112052; called by muse, mutect2, varscan2
- BARHL2 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV99059756; called by muse, mutect2, varscan2
- BCL11A | c.1102G>A p.E368K (on ENST00000335712 / NM_001365609.1; = p.E402K on NM_018014.4) | Missense Mutation (SNP) | VAF 47/394 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100185297; called by muse, mutect2, varscan2
- BCORL1 | c.5042dup p.G1682Rfs*4 | Frame Shift Ins (INS) | VAF 38/293 reads (13%) | catalogued as rs768244116, COSV54407680; called by mutect2, varscan2
- BTBD3 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs940159148; called by muse, mutect2, varscan2
- C15orf48 | c.130del p.R44Efs*20 | Frame Shift Del (DEL) | VAF 20/160 reads (13%) | catalogued as COSV60223333; called by pindel, varscan2
- C6orf58 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542531909, COSV61666963; called by muse, mutect2, varscan2
- CACNA1C | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100224136; called by muse, mutect2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 34/240 reads (14%) | catalogued as rs752398646; called by mutect2, varscan2
- CDS1 | c.789del p.F263Lfs*6 | Frame Shift Del (DEL) | VAF 22/126 reads (17%) | catalogued as rs759091263; called by mutect2, varscan2
- CEACAM1 | c.958+5_958+8del | Splice Region (DEL) | VAF 12/80 reads (15%) | catalogued as rs779826417; called by pindel, varscan2
- CEL | c.619del p.D207Tfs*41 (on ENST00000673714; = p.D204Tfs*41 on NM_001807.6) | Frame Shift Del (DEL) | VAF 28/180 reads (16%) | catalogued as rs754393686, COSV60827096; called by mutect2, pindel, varscan2
- CNOT6 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs763363186, COSV56159543; called by muse, mutect2, varscan2
- COL17A1 | c.3869G>A p.R1290Q | Missense Mutation (SNP) | VAF 52/346 reads (15%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as rs745779563; called by muse, mutect2, varscan2
- CPSF1 | c.1591G>T p.G531C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781828564; called by muse, mutect2, varscan2
- DMRT1 | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 68/368 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs1368766131; called by muse, mutect2, varscan2
- DNAJB7 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs916721222; called by muse, mutect2, varscan2
- DOCK6 | c.4523T>C p.M1508T | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as rs371193810; called by muse, mutect2, varscan2
- EFCAB6 | c.4322G>A p.R1441H | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs915086992, COSV53061397; called by muse, mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 18/96 reads (19%) | catalogued as rs768793415; called by mutect2, varscan2
- ERVMER34-1 | c.899del p.L300Cfs*33 | Frame Shift Del (DEL) | VAF 42/258 reads (16%) | catalogued as rs779855268; called by mutect2, varscan2
- FAM184B | c.2920G>A p.V974M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs183471400; called by muse, mutect2
- FAT2 | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs147663319; called by muse, mutect2, varscan2
- FCGBP | c.9388G>A p.A3130T | Missense Mutation (SNP) | VAF 60/926 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as rs367948062; called by muse, mutect2
- FMNL3 | c.1708C>T p.R570W | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781705688, COSV99527158; called by muse, mutect2, varscan2
- FRA10AC1 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as rs1440646764; called by muse, mutect2
- GALNT15 | c.409del p.A137Lfs*13 | Frame Shift Del (DEL) | VAF 29/136 reads (21%) | catalogued as COSV60215076, COSV60216772; called by mutect2, pindel, varscan2
- GEMIN5 | c.3185A>G p.K1062R | Missense Mutation (SNP) | VAF 75/452 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as rs753307822, COSV53560004; called by muse, mutect2, varscan2
- HAND2 | c.247del p.V83Cfs*16 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | catalogued as CM105646; called by mutect2, pindel, varscan2
- HSD3B1 | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778465471, COSV52489699; called by muse, mutect2
- INSC | c.1536C>T p.C512= | Splice Region (SNP) | VAF 40/224 reads (18%) | catalogued as rs1199160647; called by muse, mutect2, varscan2
- KALRN | c.6140A>G p.N2047S (on ENST00000360013 / NM_001024660.4; = p.N350S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs780163028; called by muse, mutect2, varscan2
- KATNAL1 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66064054; called by muse, mutect2, varscan2
- KCNK4 | c.1122del p.R375Gfs*43 | Frame Shift Del (DEL) | VAF 30/210 reads (14%) | catalogued as rs5792319; called by mutect2, pindel, varscan2
- KCNV1 | c.944G>T p.R315M | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV52089462; called by muse, mutect2, varscan2
- KIF26A | c.2929G>A p.A977T | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs899926229, COSV59470525; called by muse, mutect2, varscan2
- KSR1 | c.1327G>A p.D443N (on ENST00000644974 / NM_001367810.1; = p.D306N on NM_014238.2) | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1282779640; called by muse, mutect2, varscan2
- LARGE2 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as rs370411213; called by muse, mutect2, varscan2
- LLGL1 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 57/368 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as rs531770044; called by muse, mutect2, varscan2
- LTBP4 | c.4337C>T p.A1446V (on ENST00000308370 / NM_001042544.1; = p.A1409V on NM_003573.2) | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs938630641; called by muse, mutect2, varscan2
- MAN1C1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as COSV56049559; called by muse, mutect2, varscan2
- MAPK8IP1 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); catalogued as rs924695846; called by muse, mutect2
- MCF2L | c.2446G>A p.A816T (on ENST00000375608; = p.A784T on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs763829216, COSV56180386; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 41/228 reads (18%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as rs759847587; called by mutect2, varscan2
- MYH11 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375159635; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCAPD3 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1285042924; called by muse, mutect2, varscan2
- NDN | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV59360543; called by muse, mutect2
- NFATC1 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560797460, COSV53694870; called by muse, mutect2, varscan2
- NISCH | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.669); catalogued as rs1412018026; called by muse, mutect2, varscan2
- NKAPL | c.711del p.K239Rfs*39 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs201499135, COSV59197754; called by mutect2, pindel, varscan2
- NRDE2 | c.268del p.R90Gfs*69 | Frame Shift Del (DEL) | VAF 28/208 reads (13%) | catalogued as rs1249617548, COSV62963847; called by mutect2, pindel, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 31/104 reads (30%) | catalogued as rs776154715; called by mutect2, varscan2
- OR14K1 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 23/277 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs544886174, COSV99315527; called by muse, mutect2
- OR56A5 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs747820460; called by muse, mutect2, varscan2
- PAF1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as rs1483396807; called by muse, mutect2, varscan2
- PCDHA4 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 78/551 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.311); catalogued as rs199939862, COSV63541144; called by muse, mutect2, varscan2
- PDE8B | c.2225G>A p.S742N | Missense Mutation (SNP) | VAF 70/451 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs746207842, COSV53735509; called by muse, mutect2, varscan2
- PIP4K2A | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs768953642; called by muse, mutect2, varscan2
- PLCH2 | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs180707391; called by muse, mutect2, varscan2
- PLEC | c.6005G>A p.R2002H (on ENST00000322810 / NM_201380.4; = p.R1892H on NM_000445.5) | Missense Mutation (SNP) | VAF 85/648 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs569571032; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PMPCB | c.1155-3T>A | Splice Region (SNP) | VAF 18/90 reads (20%) | catalogued as COSV99971096; called by muse, mutect2, varscan2
- POLR3A | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 72/513 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV64931652; called by muse, mutect2, varscan2
- RBMS3 | c.522C>G p.D174E | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV56160161; called by muse, mutect2, varscan2
- RBPJ | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs771759532, COSV60755209; called by muse, mutect2, varscan2
- RETREG1 | c.1169C>T p.T390M (on ENST00000306320 / NM_001034850.2; = p.T249M on NM_019000.4) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs374082497; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGS10 | c.92C>T p.A31V (on ENST00000369101; = p.A25V on NM_002925.3) | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs1158651601, COSV64862050; called by muse, mutect2, varscan2
- RYR1 | c.7655G>A p.R2552H | Missense Mutation (SNP) | VAF 68/415 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CD133348; called by muse, mutect2, varscan2
- RYR3 | c.13706G>A p.R4569H (on ENST00000389232; = p.R4570H on NM_001036.6) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs540595603; called by muse, mutect2, varscan2
- SCGB1C1 | c.262G>T p.V88L | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100285224; called by muse, mutect2, varscan2
- SEBOX | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99412313; called by muse, mutect2, varscan2
- SHOX2 | c.431G>A p.R144Q (on ENST00000441443 / NM_006884.3; = p.R168Q on NM_003030.4) | Missense Mutation (SNP) | VAF 77/510 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1313229623, COSV67464336; called by muse, mutect2, varscan2
- SLC14A1 | c.1067dup p.N356Kfs*11 | Frame Shift Ins (INS) | VAF 63/373 reads (17%) | catalogued as rs756548295; called by mutect2, pindel, varscan2
- SLC2A8 | c.708del p.I237Sfs*27 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | catalogued as rs199808560; called by mutect2, pindel, varscan2
- SOD3 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 70/383 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as rs1056537271; called by muse, mutect2, varscan2
- SOX17 | c.406A>G p.K136E | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99810843; called by muse, mutect2, varscan2
- STX6 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs747975341; called by muse, mutect2, varscan2
- SUMO3 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 70/474 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs750770742, COSV60538350; called by muse, mutect2, varscan2
- TBX2 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.061); catalogued as COSV99538863; called by muse, mutect2, varscan2
- TECTA | c.4486C>T p.R1496C | Missense Mutation (SNP) | VAF 71/438 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs374337206; called by muse, mutect2, varscan2
- TEP1 | c.5684C>T p.A1895V | Missense Mutation (SNP) | VAF 58/312 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.424); catalogued as rs553923395, COSV52988125; called by muse, mutect2, varscan2
- TRIM51 | c.430del p.M144Cfs*15 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs763121810; called by mutect2, varscan2
- TTC7B | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1226973726; called by muse, mutect2, varscan2
- TTN | c.77603G>A p.R25868Q (on ENST00000591111; = p.R18444Q on NM_003319.4) | Missense Mutation (SNP) | VAF 32/196 reads (16%) | PolyPhen probably damaging (0.996); catalogued as rs1246168127, COSV59940895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE2Z | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.301); catalogued as rs759919336, COSV104417378; called by muse, mutect2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | catalogued as rs767420916; called by mutect2, varscan2
- USH2A | c.7039G>A p.V2347M | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.421); catalogued as rs727503721, COSV56395676; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS33A | c.1376dup p.R460Qfs*17 | Frame Shift Ins (INS) | VAF 29/150 reads (19%) | catalogued as rs1357715083; called by mutect2, varscan2
- VWCE | c.2033G>A p.G678E | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1246423162, COSV57115916; called by muse, mutect2, varscan2
- ZHX3 | c.2014A>G p.T672A | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV58382951; called by muse, mutect2, varscan2
- ZNF541 | c.2476G>A p.G826S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.374); catalogued as rs371040136; called by muse, mutect2, varscan2
- ZNF625 | c.480del p.K161Nfs*23 | Frame Shift Del (DEL) | VAF 32/177 reads (18%) | catalogued as COSV63242073; called by mutect2, pindel, varscan2
- ZNF750 | c.892T>A p.S298T | Missense Mutation (SNP) | VAF 80/428 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1272552863; called by muse, mutect2, varscan2
- ZSWIM3 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs751527870, COSV99666597; called by muse, mutect2, varscan2
- ACTA1 | c.830A>G p.H277R | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- ACTRT3 | c.668A>C p.E223A | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by mutect2, varscan2
- ADAMTS16 | c.2330A>G p.Y777C | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- ADARB2 | c.86G>T p.R29M | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD18B | c.1865A>C p.E622A | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.028); called by mutect2, varscan2
- ARHGAP29 | c.1489G>T p.A497S | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF17 | c.4255C>A p.L1419M | Missense Mutation (SNP) | VAF 17/406 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARPIN | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATMIN | c.463-1G>A p.X155_splice | Splice Site (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2, varscan2
- C1QTNF7 | c.191A>G p.D64G | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHPF2 | c.1751A>G p.H584R | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CLIP3 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2
- CLTC | c.3771_3779del p.F1258_C1260del | In Frame Del (DEL) | VAF 27/133 reads (20%) | called by mutect2, pindel, varscan2
- CNGB1 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 67/345 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- COL2A1 | c.79del p.D27Mfs*41 | Frame Shift Del (DEL) | VAF 28/202 reads (14%) | called by mutect2, pindel, varscan2
- CYP20A1 | c.444A>T p.E148D | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- DACH1 | c.298_303del p.G100_G101del | In Frame Del (DEL) | VAF 18/158 reads (11%) | called by pindel, varscan2
- DACH2 | c.425A>G p.N142S | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DCTN2 | c.884A>C p.K295T (on ENST00000548249 / NM_001261413.2; = p.K300T on NM_006400.4) | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- DDX54 | c.979C>A p.L327M | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- DLX2 | c.877C>A p.L293M | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- DNAJB7 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DNAJC10 | c.475T>C p.S159P | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DRGX | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 39/333 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DTNA | c.1771_1772insGTCGC p.Q591Rfs*9 | Frame Shift Ins (INS) | VAF 34/342 reads (10%) | called by mutect2, pindel
- ERN1 | c.688del p.Y230Mfs*8 | Frame Shift Del (DEL) | VAF 57/439 reads (13%) | called by mutect2, pindel, varscan2
- GAREM2 | c.2120G>A p.G707E | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.116); called by muse, mutect2
- GATA3 | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- GTF2IRD1 | c.1823A>G p.E608G | Missense Mutation (SNP) | VAF 57/314 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- HAGHL | c.133del p.V45Cfs*3 | Frame Shift Del (DEL) | VAF 26/163 reads (16%) | called by mutect2, pindel, varscan2
- HECTD1 | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- HERC5 | c.2659G>T p.G887* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- HOXC10 | c.900G>T p.E300D | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- HYDIN | c.6669G>A p.Q2223= | Splice Region (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- ICE1 | c.4708dup p.T1570Nfs*8 | Frame Shift Ins (INS) | VAF 11/96 reads (11%) | called by mutect2, pindel, varscan2
- IGHMBP2 | c.2465A>G p.Q822R | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IPO9 | c.2959G>A p.D987N | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.521); called by muse, mutect2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 20/191 reads (10%) | called by mutect2, varscan2
- JAK1 | c.425del p.K142Rfs*26 | Frame Shift Del (DEL) | VAF 42/276 reads (15%) | called by mutect2, varscan2
- KCNH3 | c.1025T>C p.L342P | Missense Mutation (SNP) | VAF 61/374 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNQ3 | c.2333A>C p.Q778P | Missense Mutation (SNP) | VAF 63/349 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- KIF1C | c.1838del p.P613Hfs*27 | Frame Shift Del (DEL) | VAF 30/154 reads (19%) | called by mutect2, pindel, varscan2
- KLHL10 | c.222C>A p.N74K | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- KLHL20 | c.1286T>G p.I429S | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.026); called by muse, varscan2
- KRT86 | c.1278_1279+2del | Frame Shift Del (DEL) | VAF 51/325 reads (16%) | called by mutect2, pindel, varscan2
- LARP1B | c.882del p.K294Nfs*20 | Frame Shift Del (DEL) | VAF 30/307 reads (10%) | called by mutect2, pindel
- LCA5 | c.1073G>A p.W358* | Nonsense Mutation (SNP) | VAF 39/227 reads (17%) | called by muse, mutect2, varscan2
- LEMD3 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); called by muse, mutect2
- MTMR3 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC5B | c.7807G>A p.A2603T | Missense Mutation (SNP) | VAF 56/386 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MYOM2 | c.1439C>A p.P480H | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NEO1 | c.1241del p.N414Mfs*12 | Frame Shift Del (DEL) | VAF 33/243 reads (14%) | called by mutect2, pindel, varscan2
- NEURL1B | c.1454del p.P485Rfs*87 | Frame Shift Del (DEL) | VAF 24/187 reads (13%) | called by mutect2, pindel
- NFKB2 | c.1117+8G>T | Splice Region (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- NHS | c.766del p.L256Ffs*28 | Frame Shift Del (DEL) | VAF 122/708 reads (17%) | called by mutect2, pindel, varscan2
- NIN | c.1304del p.N435Mfs*19 | Frame Shift Del (DEL) | VAF 29/196 reads (15%) | called by mutect2, pindel, varscan2
- NKAP | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- NKX2-6 | c.571C>A p.R191S | Missense Mutation (SNP) | VAF 249/784 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NOXO1 | c.67-3del | Splice Region (DEL) | VAF 30/213 reads (14%) | called by mutect2, pindel, varscan2
- NSMAF | c.2596G>A p.G866S | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPHN1 | c.1652T>C p.I551T | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OTOF | c.4898_4899insA p.G1634Wfs*15 (on ENST00000272371 / NM_194248.3; = p.G867Wfs*15 on NM_004802.4) | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- PALLD | c.2284A>G p.I762V (on ENST00000505667 / NM_001166108.2; = p.I745V on NM_016081.4) | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PARN | c.1609A>G p.K537E | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- PCGF3 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGA5 | c.824T>C p.I275T | Missense Mutation (SNP) | VAF 122/657 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- PHC1 | c.2524del p.M842* | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel, varscan2
- PHF20L1 | c.2476del p.I826* | Frame Shift Del (DEL) | VAF 16/176 reads (9%) | called by mutect2, pindel
- PLEKHD1 | c.411-2A>T p.X137_splice | Splice Site (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- PLPPR3 | c.1855T>A p.Y619N (on ENST00000520876 / NM_001270366.2; = p.Y647N on NM_024888.2) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PODXL | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 53/293 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPT1 | c.166del p.M56Wfs*14 (on ENST00000433473; = p.M57Wfs*14 on NM_000310.4) | Frame Shift Del (DEL) | VAF 42/249 reads (17%) | called by mutect2, pindel, varscan2
- PRB3 | c.626del p.P209Hfs*140 (on ENST00000381842; = p.P251Hfs*? on NM_006249.5) | Frame Shift Del (DEL) | VAF 8/79 reads (10%) | called by pindel, varscan2
- PSMB3 | c.500T>C p.I167T | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- PTK2B | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PTPN2 | c.1141del p.R381Gfs*47 | Frame Shift Del (DEL) | VAF 51/307 reads (17%) | called by mutect2, varscan2
- PXDNL | c.4345G>A p.V1449I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- RNF170 | c.304T>G p.C102G | Missense Mutation (SNP) | VAF 61/462 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERINC3 | c.829C>A p.L277I | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- SETD2 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIGLEC5 | c.876del p.I293Sfs*12 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | called by mutect2, varscan2
- SLC30A5 | c.1440-3del | Splice Region (DEL) | VAF 15/114 reads (13%) | called by mutect2, pindel, varscan2
- SLK | c.3603A>T p.E1201D | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SMCO2 | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- SON | c.2242T>C p.S748P | Missense Mutation (SNP) | VAF 85/412 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- SYN3 | c.114del p.A39Pfs*29 | Frame Shift Del (DEL) | VAF 26/124 reads (21%) | called by mutect2, pindel, varscan2
- TECTA | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- TGFBRAP1 | c.729del p.V244Cfs*7 | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | called by mutect2, pindel, varscan2
- THAP11 | c.110T>G p.L37R | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TMEM54 | c.352A>T p.M118L | Missense Mutation (SNP) | VAF 43/280 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TOB2 | c.96dup p.E33Rfs*9 | Frame Shift Ins (INS) | VAF 29/243 reads (12%) | called by mutect2, pindel, varscan2
- TOMM70 | c.504dup p.W169Mfs*13 | Frame Shift Ins (INS) | VAF 8/58 reads (14%) | called by mutect2, pindel
- TRAPPC8 | c.756T>G p.N252K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.021); called by muse, varscan2
- TRAV26-1 | c.209del p.N70Tfs*10 | Frame Shift Del (DEL) | VAF 30/158 reads (19%) | called by mutect2, pindel, varscan2
- TRIM33 | c.2134_2135dup p.Q712Hfs*7 | Frame Shift Ins (INS) | VAF 33/225 reads (15%) | called by mutect2, pindel, varscan2
- TRPM7 | c.2347T>C p.S783P | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- TTC16 | c.1636del p.E546Sfs*3 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- USH2A | c.1420C>A p.P474T | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- USP47 | c.2717A>C p.E906A (on ENST00000399455 / NM_001372095.1; = p.E818A on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- UTF1 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 83/547 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- VEGFD | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- VIRMA | c.2163del p.F721Lfs*11 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, varscan2
- XPO5 | c.942del p.K314Nfs*6 | Frame Shift Del (DEL) | VAF 33/203 reads (16%) | called by mutect2, pindel, varscan2
- XRCC6 | c.387del p.K129Nfs*6 | Frame Shift Del (DEL) | VAF 34/226 reads (15%) | called by mutect2, pindel, varscan2
- ZC3HC1 | c.492A>G p.P164= | Splice Region (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- ZGRF1 | c.5825T>G p.L1942R | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ZIC1 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ZNF438 | c.1657C>T p.H553Y | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AATK | c.270C>T p.P90= | Silent (SNP) | VAF 47/288 reads (16%) | catalogued as rs529248449; called by muse, mutect2, varscan2
- ABCC10 | c.1243C>T p.L415= (on ENST00000372530 / NM_001198934.2; = p.L372= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/224 reads (19%) | called by muse, mutect2, varscan2
- ACOT12 | c.591C>T p.H197= | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as rs149420016; called by muse, mutect2, varscan2
- ADGRL2 | c.870G>A p.Q290= | Silent (SNP) | VAF 74/502 reads (15%) | catalogued as rs1427896297; called by muse, mutect2, varscan2
- AGO2 | c.2163C>T p.N721= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs778030800, COSV55046728; called by muse, mutect2, varscan2
- ALPL | c.666C>T p.G222= | Silent (SNP) | VAF 28/171 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.156C>T p.G52= | Silent (SNP) | VAF 41/201 reads (20%) | catalogued as rs1265760052; called by muse, mutect2, varscan2
- BAIAP2L2 | c.328C>T p.L110= | Silent (SNP) | VAF 17/87 reads (20%) | called by muse, mutect2, varscan2
- CCDC106 | c.396T>C p.P132= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as rs748844748; called by muse, mutect2, varscan2
- CDC42BPG | c.4437G>A p.R1479= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- CEMIP | c.921T>C p.H307= | Silent (SNP) | VAF 87/473 reads (18%) | catalogued as rs373591542; called by muse, mutect2, varscan2
- CETN1 | c.465C>T p.G155= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs745607980, COSV59121487; called by muse, mutect2
- CHCHD7 | c.108G>A p.R36= (on ENST00000355315 / NM_001011671.3; = p.R48= on NM_024300.4) | Silent (SNP) | VAF 21/165 reads (13%) | catalogued as rs777965569; called by muse, mutect2, varscan2
- COL5A3 | c.4914G>A p.L1638= | Silent (SNP) | VAF 57/335 reads (17%) | called by muse, mutect2, varscan2
- CPM | c.792A>G p.G264= | Silent (SNP) | VAF 25/208 reads (12%) | called by muse, mutect2, varscan2
- CR2 | c.492T>C p.H164= | Silent (SNP) | VAF 42/307 reads (14%) | catalogued as rs1248758541; called by muse, mutect2, varscan2
- DAXX | c.1365G>A p.E455= | Silent (SNP) | VAF 59/299 reads (20%) | catalogued as rs755501402, COSV56472463; called by muse, mutect2, varscan2
- DNAH5 | c.9735G>A p.V3245= | Silent (SNP) | VAF 23/206 reads (11%) | catalogued as rs752312859, COSV54234572; called by muse, mutect2, varscan2
- DNAJC5 | c.438G>A p.T146= | Silent (SNP) | VAF 66/359 reads (18%) | catalogued as rs746222594; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- EDA2R | c.441A>G p.L147= | Silent (SNP) | VAF 41/270 reads (15%) | catalogued as rs1448824706; called by muse, mutect2, varscan2
- EGF | c.2784C>T p.S928= | Silent (SNP) | VAF 36/230 reads (16%) | called by muse, mutect2, varscan2
- EML1 | c.1470C>T p.N490= | Silent (SNP) | VAF 32/272 reads (12%) | called by muse, mutect2, varscan2
- EPHA2 | c.957C>T p.D319= | Silent (SNP) | VAF 76/426 reads (18%) | called by muse, mutect2, varscan2
- EXOC4 | c.2109C>T p.D703= | Silent (SNP) | VAF 33/251 reads (13%) | catalogued as rs1485010562, COSV54109224; called by muse, mutect2, varscan2
- FANCC | c.1290C>T p.Y430= | Silent (SNP) | VAF 47/240 reads (20%) | catalogued as rs766105286, COSV56662446; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- FASTKD5 | c.2109C>T p.N703= | Silent (SNP) | VAF 39/251 reads (16%) | called by muse, mutect2, varscan2
- FBLN7 | c.180C>T p.S60= | Silent (SNP) | VAF 34/196 reads (17%) | called by muse, mutect2, varscan2
- FCRL5 | c.669G>A p.P223= | Silent (SNP) | VAF 58/534 reads (11%) | catalogued as rs761744976, COSV62514453; called by muse, mutect2, varscan2
- GALNT5 | c.2760A>T p.V920= | Silent (SNP) | VAF 37/187 reads (20%) | called by muse, mutect2, varscan2
- GCNT2 | c.726C>A p.S242= | Silent (SNP) | VAF 41/176 reads (23%) | called by muse, mutect2, varscan2
- GPA33 | c.87C>T p.D29= | Silent (SNP) | VAF 27/214 reads (13%) | catalogued as rs199696976; called by muse, mutect2, varscan2
- HCN1 | c.717A>G p.V239= | Silent (SNP) | VAF 35/270 reads (13%) | catalogued as rs1354539677; called by muse, mutect2, varscan2
- HGSNAT | c.621C>A p.R207= | Silent (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2, varscan2
- HMBOX1 | c.948A>G p.S316= | Silent (SNP) | VAF 30/196 reads (15%) | called by muse, mutect2, varscan2
- ID4 | c.303C>T p.I101= | Silent (SNP) | VAF 63/389 reads (16%) | catalogued as rs779614068; called by muse, mutect2, varscan2
- IFT172 | c.3000T>C p.P1000= | Silent (SNP) | VAF 33/167 reads (20%) | called by muse, mutect2, varscan2
- IGHM | c.891C>T p.S297= | Silent (SNP) | VAF 104/667 reads (16%) | catalogued as rs781861965; called by muse, mutect2, varscan2
- KATNBL1 | c.819T>C p.S273= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2
- KCNA5 | c.621C>T p.D207= | Silent (SNP) | VAF 55/348 reads (16%) | catalogued as rs779034667; called by muse, mutect2, varscan2
- KLRG2 | c.507C>T p.H169= | Silent (SNP) | VAF 11/270 reads (4%) | called by muse, mutect2
- KMT2A | c.11158C>T p.L3720= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2
- LOXHD1 | c.6594C>T p.F2198= (on ENST00000642948; = p.F2136= on NM_144612.7) | Silent (SNP) | VAF 135/811 reads (17%) | catalogued as rs981453947, COSV56070626; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRP1 | c.9318G>A p.G3106= | Silent (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- LRP6 | c.1269C>T p.G423= | Silent (SNP) | VAF 14/305 reads (5%) | catalogued as rs890268575; called by muse, mutect2
- MAP3K6 | c.3678G>A p.Q1226= | Silent (SNP) | VAF 14/230 reads (6%) | called by muse, mutect2
- MAP7D1 | c.481C>T p.L161= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- MAPT | c.1830A>G p.P610= (on ENST00000262410 / NM_001377265.1; = p.P218= on NM_005910.5) | Silent (SNP) | VAF 15/310 reads (5%) | catalogued as rs767566992; called by muse, mutect2
- MFSD6 | c.1194C>T p.N398= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as rs372117138; called by muse, mutect2, varscan2
- MYO9B | c.4677C>T p.H1559= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs374282860; called by muse, mutect2, varscan2
- MYOCD | c.2787T>G p.S929= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- MYOM1 | c.573G>A p.T191= | Silent (SNP) | VAF 61/414 reads (15%) | catalogued as rs199937869; called by muse, mutect2, varscan2
- NKX2-6 | c.81G>A p.A27= | Silent (SNP) | VAF 34/302 reads (11%) | called by muse, mutect2, varscan2
- OBSCN | c.1014G>A p.R338= | Silent (SNP) | VAF 56/533 reads (11%) | called by muse, mutect2, varscan2
- P2RY2 | c.153C>T p.N51= | Silent (SNP) | VAF 12/203 reads (6%) | called by muse, mutect2
- PDCD11 | c.4572G>A p.K1524= | Silent (SNP) | VAF 15/140 reads (11%) | called by muse, mutect2, varscan2
- PDLIM2 | c.699G>T p.R233= (on ENST00000397760; = p.R483= on NM_021630.6) | Silent (SNP) | VAF 66/462 reads (14%) | called by muse, varscan2
- PHF8 | c.1878C>T p.T626= (on ENST00000357988 / NM_001184896.1; = p.T590= on NM_015107.3) | Silent (SNP) | VAF 30/211 reads (14%) | called by muse, mutect2, varscan2
- PITPNM3 | c.363G>A p.P121= | Silent (SNP) | VAF 49/390 reads (13%) | catalogued as rs375235477; called by muse, mutect2, varscan2
- PLAA | c.1239A>G p.G413= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- POGZ | c.1135C>A p.R379= | Silent (SNP) | VAF 25/205 reads (12%) | called by muse, mutect2, varscan2
- POLI | c.279T>C p.Y93= | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- PRRC2B | c.2280G>A p.P760= | Silent (SNP) | VAF 36/211 reads (17%) | catalogued as rs375886289; called by muse, mutect2, varscan2
- PTPN13 | c.6111G>A p.L2037= (on ENST00000411767 / NM_080683.3; = p.L2018= on NM_006264.3) | Silent (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- PTPRO | c.3363C>T p.V1121= (on ENST00000281171 / NM_030667.3; = p.V1093= on NM_002848.4) | Silent (SNP) | VAF 49/293 reads (17%) | catalogued as rs140884816, COSV55511642; called by muse, mutect2, varscan2
- RNF148 | c.453C>T p.V151= | Silent (SNP) | VAF 51/272 reads (19%) | catalogued as rs757541231, COSV57357252; called by muse, mutect2, varscan2
- RYR1 | c.12084G>A p.S4028= | Silent (SNP) | VAF 80/514 reads (16%) | catalogued as rs571477269, COSV62099200; called by muse, mutect2, varscan2
- SAMD4A | c.1962C>T p.S654= | Silent (SNP) | VAF 31/142 reads (22%) | called by muse, mutect2, varscan2
- SART3 | c.1524G>A p.Q508= (on ENST00000228284; = p.Q490= on NM_014706.4) | Silent (SNP) | VAF 77/445 reads (17%) | called by muse, mutect2, varscan2
- SLC26A2 | c.876T>C p.H292= | Silent (SNP) | VAF 69/368 reads (19%) | called by muse, mutect2, varscan2
- SLC45A2 | c.1428C>T p.C476= | Silent (SNP) | VAF 80/453 reads (18%) | catalogued as rs139551409; called by muse, mutect2, varscan2
- SLC5A7 | c.102C>T p.S34= | Silent (SNP) | VAF 29/191 reads (15%) | catalogued as rs778941657, COSV50888948; called by muse, mutect2, varscan2
- SMARCD3 | c.657T>C p.P219= (on ENST00000262188 / NM_001003801.2; = p.P206= on NM_003078.4) | Silent (SNP) | VAF 37/236 reads (16%) | catalogued as COSV99223279; called by muse, mutect2, varscan2
- TECTA | c.5329C>T p.L1777= | Silent (SNP) | VAF 22/175 reads (13%) | called by muse, mutect2, varscan2
- TRAJ44 | c.63C>T p.L21= | Silent (SNP) | VAF 20/177 reads (11%) | catalogued as rs771591750; called by muse, mutect2, varscan2
- TTBK1 | c.1392G>A p.T464= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs372795434; called by mutect2, varscan2
- TTN | c.68778A>G p.S22926= (on ENST00000591111; = p.S15502= on NM_003319.4) | Silent (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- USP17L2 | c.1200C>T p.D400= | Silent (SNP) | VAF 158/1135 reads (14%) | called by muse, mutect2, varscan2
- VSTM2B | c.129C>T p.D43= | Silent (SNP) | VAF 37/203 reads (18%) | catalogued as COSV59263531; called by muse, mutect2, varscan2
- VWDE | c.378C>T p.C126= | Silent (SNP) | VAF 27/175 reads (15%) | called by muse, mutect2, varscan2
- WDFY4 | c.9048C>T p.H3016= | Silent (SNP) | VAF 43/256 reads (17%) | catalogued as rs570371127; called by muse, mutect2, varscan2
- WDR6 | c.909C>T p.A303= | Silent (SNP) | VAF 30/171 reads (18%) | catalogued as COSV100556531; called by muse, mutect2, varscan2
- ZAN | c.5100C>T p.G1700= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as rs781312732, COSV61815382; called by muse, mutect2, varscan2
- ZFR2 | c.1173G>A p.A391= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as rs963844831, COSV53596101; called by muse, mutect2, varscan2
- ZNF219 | c.420A>G p.S140= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100070666; called by muse, mutect2, varscan2
- ZNF234 | c.1491A>G p.A497= | Silent (SNP) | VAF 41/229 reads (18%) | catalogued as rs766518743; called by muse, mutect2, varscan2
- ZNF532 | c.573G>A p.T191= | Silent (SNP) | VAF 33/204 reads (16%) | catalogued as rs371823083, COSV60172659; called by muse, mutect2, varscan2
- ZNF703 | c.312G>A p.P104= | Silent (SNP) | VAF 38/228 reads (17%) | called by muse, mutect2, varscan2
- ZNF843 | c.540C>T p.S180= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as rs762355389; called by muse, mutect2, varscan2
- AF196969.1 | c.-22G>A | 5'UTR (SNP) | VAF 58/304 reads (19%) | catalogued as rs782746968, COSV99339291; called by muse, mutect2, varscan2
- AL359555.4 | n.274C>A | RNA (SNP) | VAF 18/64 reads (28%) | catalogued as rs971115981; called by muse, mutect2, varscan2
- ARAP1 | c.4121+11G>A | Intron (SNP) | VAF 53/277 reads (19%) | catalogued as rs768666873; called by muse, mutect2, varscan2
- ATIC | c.-44G>A | 5'UTR (SNP) | VAF 68/391 reads (17%) | catalogued as rs1169058506; called by muse, mutect2, varscan2
- ATL1 | c.-24A>G | 5'UTR (SNP) | VAF 14/183 reads (8%) | called by muse, mutect2
- BLOC1S5-TXNDC5 | c.372+38678G>T | Intron (SNP) | VAF 46/386 reads (12%) | called by muse, mutect2, varscan2
- C22orf34 | n.820T>C | RNA (SNP) | VAF 17/123 reads (14%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.151+25498G>A | Intron (SNP) | VAF 83/512 reads (16%) | catalogued as rs527709007; called by mutect2, varscan2
- CBX2 | c.*8G>A | 3'UTR (SNP) | VAF 17/165 reads (10%) | called by muse, mutect2, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 6/39 reads (15%) | catalogued as rs73150876; called by muse, mutect2, varscan2
- CENPP | c.*6426C>T | 3'UTR (SNP) | VAF 22/137 reads (16%) | catalogued as rs747961441, COSV99845754; called by muse, mutect2, varscan2
- CLEC18C | c.*3C>A | 3'UTR (SNP) | VAF 21/165 reads (13%) | called by mutect2, varscan2
- CTBP1 | chr4:1250705 C>T | 5'Flank (SNP) | VAF 24/145 reads (17%) | catalogued as rs773888918; called by muse, mutect2, varscan2
- CTTNBP2 | c.3348+1002_3348+1003del | Intron (DEL) | VAF 10/82 reads (12%) | catalogued as rs1367454035; called by pindel, varscan2
- CYP17A1 | c.298-27T>A | Intron (SNP) | VAF 46/317 reads (15%) | called by muse, mutect2, varscan2
- DPP4 | c.6+40G>A | Intron (SNP) | VAF 22/129 reads (17%) | called by muse, mutect2, varscan2
- FCMR | c.37+471A>G | Intron (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- FLCN | c.871+101G>A | Intron (SNP) | VAF 77/504 reads (15%) | catalogued as rs888633327; called by muse, mutect2, varscan2
- FRMD8P1 | n.499C>T | RNA (SNP) | VAF 81/533 reads (15%) | called by muse, mutect2, varscan2
- GABRA6 | c.530-50dup | Intron (INS) | VAF 13/72 reads (18%) | catalogued as rs745531277; called by mutect2, varscan2
- GDF6 | c.*49C>T | 3'UTR (SNP) | VAF 26/183 reads (14%) | catalogued as COSV54624152; called by muse, mutect2, varscan2
- HMGN2P15 | n.216T>C | RNA (SNP) | VAF 74/425 reads (17%) | called by muse, mutect2, varscan2
- IRAK3 | c.-18_-3del | 5'UTR (DEL) | VAF 44/332 reads (13%) | called by mutect2, pindel
- KCTD19 | c.301-987G>T | Intron (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- KLHL32 | c.-5G>A | 5'UTR (SNP) | VAF 21/174 reads (12%) | called by muse, mutect2, varscan2
- LARP1B | c.988+611C>T | Intron (SNP) | VAF 29/140 reads (21%) | catalogued as rs1240912020; called by muse, mutect2, varscan2
- LINC00482 | n.579G>A | RNA (SNP) | VAF 9/60 reads (15%) | catalogued as rs749039493; called by muse, mutect2
- LINC01553 | n.1345T>C | RNA (SNP) | VAF 31/317 reads (10%) | catalogued as rs1372413627; called by muse, mutect2, varscan2
- MAN1B1 | c.1896+32_1896+37del | Intron (DEL) | VAF 26/164 reads (16%) | called by mutect2, pindel, varscan2
- NES | c.-2G>T | 5'UTR (SNP) | VAF 92/600 reads (15%) | called by muse, mutect2, varscan2
- OSBPL5 | chr11:3166655 A>G | 5'Flank (SNP) | VAF 36/296 reads (12%) | called by muse, mutect2, varscan2
- PABPC4 | c.1405+11G>A | Intron (SNP) | VAF 36/218 reads (17%) | catalogued as rs551051840; called by muse, mutect2, varscan2
- PDLIM2 | c.763+58G>C | Intron (SNP) | VAF 32/116 reads (28%) | called by muse, varscan2
- PKD1L2 | n.3106C>A | RNA (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2
- PTENP1 | n.1849A>G | RNA (SNP) | VAF 58/310 reads (19%) | called by muse, mutect2, varscan2
- RUNX2 | c.-10del | 5'UTR (DEL) | VAF 45/238 reads (19%) | catalogued as rs748951752; called by mutect2, varscan2
- RXRB | c.993+44G>A | Intron (SNP) | VAF 31/143 reads (22%) | called by muse, mutect2, varscan2
- SAMHD1 | c.1641+45del | Intron (DEL) | VAF 46/212 reads (22%) | called by mutect2, pindel, varscan2
- SMAD5 | chr5:136187167 C>T | 3'Flank (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- SORBS2 | c.-197-5977A>G | Intron (SNP) | VAF 40/261 reads (15%) | called by muse, mutect2, varscan2
- SP100 | c.587-182C>T | Intron (SNP) | VAF 38/297 reads (13%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133568254 G>A | 5'Flank (SNP) | VAF 35/288 reads (12%) | catalogued as rs772954109; called by muse, mutect2, varscan2
- TNFRSF10B | c.*1050A>G | 3'UTR (SNP) | VAF 80/598 reads (13%) | called by muse, mutect2, varscan2
- TNRC18 | c.187+344G>C | Intron (SNP) | VAF 19/100 reads (19%) | catalogued as rs1222647973; called by muse, mutect2, varscan2
- TP53AIP1 | c.141+135G>A | Intron (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- TSPYL4 | chr6:116258878 C>T | 5'Flank (SNP) | VAF 68/403 reads (17%) | catalogued as rs1039582651; called by muse, mutect2, varscan2
- TUBAL3 | c.-36A>G | 5'UTR (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- VAPB | c.*2854C>T | 3'UTR (SNP) | VAF 28/216 reads (13%) | called by muse, mutect2, varscan2
- WT1 | chr11:32438398 C>A | 5'Flank (SNP) | VAF 18/88 reads (20%) | catalogued as rs1169781180; called by muse, mutect2, varscan2
- ZFAT | c.-22del | 5'UTR (DEL) | VAF 28/155 reads (18%) | catalogued as rs746459398; called by mutect2, varscan2
